Somatic mutation profile of tumor specimen TCGA-75-5122-01A (aliquot TCGA-75-5122-01A-01D-1753-08) from TCGA case TCGA-75-5122, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-5122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea41d101-66ef-46fd-854f-4dc83825bd31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-5122-10A (Blood Derived Normal), aliquot TCGA-75-5122-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8755d74-d76b-44da-8a70-e00545e9de66

The open-access MAF lists 140 somatic variants for this specimen: 98 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 39, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 2, Splice Site 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+2T>C p.X1010_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- ACKR4 | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391711; called by mutect2, varscan2
- ADAMTS16 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57008405; called by muse, mutect2
- AKR1B10 | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62056715; called by muse, mutect2, varscan2
- AKT2 | c.596C>G p.T199S | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.718); catalogued as COSV60910593; called by muse, mutect2, varscan2
- ANKRD44 | c.111G>T p.L37= | Splice Region (SNP) | VAF 15/263 reads (6%) | catalogued as COSV56567072; called by muse, mutect2
- ARHGAP9 | c.371G>T p.R124M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.28); catalogued as COSV62724619; called by muse, mutect2, varscan2
- ARPP21 | c.2000G>T p.S667I | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV51809224; called by muse, mutect2
- BPI | c.727C>A p.P243T (on ENST00000262865; = p.P239T on NM_001725.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV53408694; called by muse, mutect2, varscan2
- C2CD5 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61727838, COSV61728117; called by muse, mutect2, varscan2
- CALR | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100330496; called by muse, mutect2
- CDH18 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56963913; called by muse, mutect2
- CGNL1 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV55563012; called by muse, mutect2
- CHST15 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV60565015, COSV60566151; called by muse, mutect2, varscan2
- CMYA5 | c.6175C>A p.Q2059K | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.057); catalogued as rs754427550, COSV71409861; called by muse, mutect2, varscan2
- COL15A1 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV66649740; called by muse, mutect2, varscan2
- COL5A1 | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV65675539; called by muse, mutect2, varscan2
- CRACD | c.3512A>T p.K1171M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51732506; called by muse, mutect2, varscan2
- CSDE1 | c.1775C>G p.A592G (on ENST00000358528 / NM_001007553.3; = p.A561G on NM_007158.6) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as COSV54761725; called by muse, mutect2
- CYP7B1 | c.1300A>T p.K434* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV59597935; called by muse, mutect2
- DPPA2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs1459790407, COSV101524800, COSV72118350; called by muse, mutect2, varscan2
- EIF4G1 | c.4472T>A p.I1491N (on ENST00000346169 / NM_198241.3; = p.I1296N on NM_004953.5) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59994494, COSV59995108; called by muse, mutect2
- FAM83D | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54159342; called by muse, mutect2, varscan2
- FAT1 | c.8208C>G p.S2736R | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV71676187; called by muse, mutect2
- FAT3 | c.3463C>A p.P1155T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV53162135; called by muse, mutect2
- FOCAD | c.3404A>T p.Y1135F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV58108349; called by muse, mutect2
- FOCAD | c.3406A>T p.N1136Y | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1327401294, COSV58108356; called by muse, mutect2
- FRAS1 | c.5678G>C p.G1893A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV53652190; called by muse, mutect2
- GPATCH3 | c.576A>T p.R192S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV64652780; called by muse, mutect2, varscan2
- GRB10 | c.1617T>G p.I539M (on ENST00000398812; = p.I493M on NM_001001549.3) | Missense Mutation (SNP) | VAF 100/455 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60017219; called by muse, mutect2, varscan2
- GRIA2 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as COSV99643383; called by muse, mutect2, varscan2
- GRIK4 | c.1305C>A p.H435Q | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.718); catalogued as COSV70807629; called by muse, mutect2
- GRIN2B | c.3135G>C p.K1045N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV74208197; called by muse, mutect2
- IFNG | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 165/191 reads (86%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as rs753611452, COSV57491582; called by muse, mutect2, varscan2
- IGKV1D-17 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs755689747; called by muse, mutect2
- IRX3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1180595468, COSV100315208; called by muse, mutect2
- ITSN1 | c.3640G>C p.D1214H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV66086392; called by muse, mutect2, varscan2
- KCNJ3 | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV54545459; called by muse, mutect2
- KIAA1549L | c.5435A>C p.D1812A (on ENST00000321505; = p.D2109A on NM_012194.3) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV58596711; called by muse, mutect2, varscan2
- LARGE1 | c.106+1G>A p.X36_splice | Splice Site (SNP) | VAF 12/160 reads (8%) | catalogued as COSV61664164; called by muse, mutect2
- MACF1 | c.6550G>C p.E2184Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV57146329; called by muse, mutect2
- MACF1 | c.7487G>C p.R2496T | Missense Mutation (SNP) | VAF 15/185 reads (8%) | catalogued as COSV57124679, COSV57133430; called by muse, mutect2
- MOGAT3 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56173137; called by muse, mutect2
- MSX1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV66947960; called by muse, mutect2
- MYH11 | c.5792G>A p.G1931E | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV55571583; called by muse, mutect2, varscan2
- NAV2 | c.3810C>G p.N1270K (on ENST00000396087 / NM_001244963.2; = p.N1247K on NM_145117.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60665901; called by muse, mutect2
- NCAM1 | c.2177G>T p.G726V (on ENST00000316851 / NM_181351.5; = p.G716V on NM_000615.7) | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57525753; called by muse, mutect2, varscan2
- NCOA7 | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57660813; called by muse, mutect2, varscan2
- NLRP3 | c.2351G>C p.C784S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV60222219, COSV60231591; called by muse, mutect2, varscan2
- NRXN1 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs868176456, COSV68050043; called by muse, mutect2
- OR2T34 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV100170587; called by muse, mutect2
- OSMR | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57092637; called by muse, mutect2
- PABPC1L | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53840364; called by muse, mutect2
- PARP8 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as rs765385797, COSV55867471; called by muse, mutect2, varscan2
- PCDHA12 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs1554169905, COSV56550063; called by muse, mutect2, varscan2
- PCDHGA2 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV54040233; called by muse, mutect2, varscan2
- PDS5A | c.2451G>C p.K817N | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.738); catalogued as COSV57831913; called by muse, mutect2
- PIGV | c.1213T>C p.F405L | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1057515509, COSV99314794; called by muse, mutect2
- PKHD1 | c.2756G>T p.G919V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61896375; called by muse, mutect2, varscan2
- PTGR2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50867052; called by muse, mutect2, varscan2
- PTX4 | c.1315G>C p.V439L (on ENST00000447419 / NM_001328608.2; = p.V434L on NM_001013658.1) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV53520234; called by muse, mutect2, varscan2
- RABEP1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs778775974, COSV52588911; called by muse, mutect2, varscan2
- RNF150 | c.597C>A p.N199K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV60789713; called by muse, mutect2, varscan2
- RSC1A1 | c.1764G>T p.Q588H | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV60781658; called by muse, mutect2, varscan2
- SEMA6D | c.2879G>T p.R960I (on ENST00000316364 / NM_153618.2; = p.R898I on NM_020858.2) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV60384749; called by muse, mutect2, varscan2
- SERINC1 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100305098; called by muse, mutect2, varscan2
- SGO2 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV63418439; called by muse, mutect2, varscan2
- SLAMF1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV52502482; called by muse, mutect2, varscan2
- SLC28A3 | c.491G>A p.R164K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1021292925, COSV66155143; called by muse, mutect2, varscan2
- SLCO6A1 | c.1819G>T p.V607L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as COSV65815217; called by muse, mutect2, varscan2
- SMC1A | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV59132137; called by muse, mutect2
- SORCS1 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99544150; called by muse, mutect2, varscan2
- SPATA31A3 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.629); catalogued as rs752795484; called by muse, mutect2, varscan2
- SPEN | c.10475C>A p.S3492Y | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV65270811, COSV65272110; called by muse, mutect2
- SYCP2L | c.2213C>A p.P738Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV51657992; called by muse, mutect2, varscan2
- SYT4 | c.1249G>C p.A417P | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54904479; called by muse, mutect2
- SYTL5 | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV99936962; called by muse, mutect2, varscan2
- TENM2 | c.6104G>T p.S2035I (on ENST00000518659 / NM_001122679.2; = p.S1796I on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV69143055; called by muse, mutect2
- TKTL2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54921474; called by muse, varscan2
- TLL1 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50329598; called by muse, mutect2, varscan2
- TPCN1 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.327); catalogued as COSV59240953; called by muse, mutect2, varscan2
- TPTE | c.800T>A p.V267D (on ENST00000618007 / NM_199261.4; = p.V249D on NM_199259.4) | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1314690861; called by muse, mutect2
- TRIM54 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56081393; called by muse, mutect2
- TRIM75P | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV72295916; called by muse, mutect2
- TRPC5 | c.2507C>G p.S836C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV53303669; called by muse, mutect2, varscan2
- TYW3 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61718724; called by muse, mutect2, varscan2
- UGT2B11 | c.1505C>A p.A502E | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV71424479; called by muse, mutect2
- WDR38 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62161527; called by muse, mutect2, varscan2
- WDR90 | c.4794C>G p.D1598E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53475896; called by muse, mutect2, varscan2
- WEE1 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.798); catalogued as COSV55198525; called by muse, mutect2, varscan2
- ABCA13 | c.13508del p.N4503Tfs*25 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel*, varscan2
- CKAP2 | c.1264A>T p.K422* (on ENST00000378037 / NM_001098525.2; = p.K421* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- GUCY1A2 | c.1694dup p.E566Gfs*5 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- ITGA4 | c.1293_1295del p.Q432del | In Frame Del (DEL) | VAF 14/159 reads (9%) | called by mutect2, pindel
- MUC5B | c.7430C>T p.P2477L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC3 | c.2848_2853del p.P950_Q951del | In Frame Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
- SUN1 | c.1312del p.E438Kfs*45 (on ENST00000405266 / NM_001367651.1; = p.E318Kfs*45 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, varscan2
- UBR4 | c.3445del p.H1149Ifs*136 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.1926C>T p.A642= | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as rs946412352, COSV50803903; called by muse, mutect2
- ARSF | c.567C>G p.L189= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV63841234; called by muse, mutect2
- ATP1A2 | c.390G>C p.L130= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100767690, COSV63406133; called by muse, mutect2
- CASP8AP2 | c.2286C>T p.S762= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as COSV52750198, COSV99387045; called by muse, mutect2
- CGGBP1 | c.324G>T p.V108= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100531816; called by muse, mutect2, varscan2
- DPYSL2 | c.1092C>T p.V364= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV60785446; called by muse, mutect2
- EFR3A | c.1074G>C p.G358= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV54462875; called by muse, mutect2
- FAM83A | c.381C>G p.P127= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV52688448; called by muse, mutect2, varscan2
- FBN2 | c.1410C>T p.G470= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs750103822, COSV52547111; ClinVar: likely benign; called by muse, mutect2
- FRS2 | c.336G>A p.V112= | Silent (SNP) | VAF 17/465 reads (4%) | catalogued as COSV100165796; called by muse, mutect2
- GPR63 | c.192A>T p.T64= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV57743859; called by muse, mutect2, varscan2
- GPT2 | c.687C>T p.I229= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV60840382; called by muse, mutect2
- GTPBP2 | c.1065C>T p.A355= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs773573064, COSV61077451; called by muse, mutect2, varscan2
- GYPA | c.246A>G p.Q82= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV51638496; called by muse, mutect2, varscan2
- HOXA3 | c.1098C>T p.F366= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV57828688; called by muse, mutect2, varscan2
- IGHV4-34 | c.75G>T p.L25= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- IGLV5-45 | c.312G>A p.G104= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as rs768753806; called by muse, mutect2, varscan2
- IRS4 | c.3675C>A p.P1225= | Silent (SNP) | VAF 61/186 reads (33%) | catalogued as COSV64536160; called by muse, mutect2, varscan2
- KIAA1755 | c.1962C>T p.T654= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54081157; called by muse, mutect2, varscan2
- LRRC47 | c.1146C>A p.A382= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV65563869; called by muse, mutect2, varscan2
- LRTM2 | c.330C>A p.S110= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99765243; called by muse, mutect2
- MARS1 | c.2643A>G p.K881= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV56259018; called by muse, mutect2, varscan2
- MGMT | c.378C>A p.T126= (on ENST00000306010; = p.T95= on NM_002412.5) | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as COSV100022579; called by muse, mutect2
- MS4A6A | c.81C>T p.P27= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as rs777841438, COSV60620383, COSV60620483; called by muse, mutect2, varscan2
- NUMA1 | c.6190C>T p.L2064= | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs762132845, COSV52620496, COSV99475031; called by muse, mutect2
- OR5L2 | c.291C>T p.C97= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as COSV65723320, COSV65725252; called by muse, mutect2, varscan2
- P2RX1 | c.963C>T p.G321= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as COSV56656086; called by muse, mutect2, varscan2
- PABPC5 | c.225C>A p.A75= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57043391; called by muse, mutect2, varscan2
- PAGR1 | c.669G>A p.R223= | Silent (SNP) | VAF 32/204 reads (16%) | catalogued as COSV100232623; called by muse, mutect2, varscan2
- PCDHB1 | c.1129C>A p.R377= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV100128058; called by muse, mutect2
- PCDHGB6 | c.453A>T p.R151= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV54042276; called by muse, mutect2, varscan2
- PKD1L1 | c.5379G>A p.P1793= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs752517738, COSV56979416; called by muse, mutect2, varscan2
- PPIP5K2 | c.1680C>G p.L560= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV58610338; called by muse, mutect2, varscan2
- SPEG | c.4137G>A p.L1379= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV56680521; called by muse, mutect2
- STX16 | c.192A>G p.P64= (on ENST00000371141 / NM_001001433.3; = p.P43= on NM_003763.6) | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV56608609; called by muse, mutect2
- TGFBRAP1 | c.663C>T p.F221= | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as COSV51516660; called by muse, mutect2
- THBS2 | c.15G>T p.L5= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- TRIML1 | c.633G>A p.L211= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV60197128; called by muse, mutect2, varscan2
- ZPBP | c.558T>C p.Y186= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV50435528; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701119 C>A | 3'Flank (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- CNEP1R1 | c.25+347C>T | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as COSV101208038; called by muse, mutect2, varscan2
- SNORD115-2 | n.7A>C | RNA (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
